Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QH-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3
Pheochromocytoma NOS
8700/0
Site ④ Adrenal gland NOS
C74.9
JW 7/24/13

Surgical Pathology Consultation Report * Amended *

Patient Name:		Accession #:
MRN:	Service:	Collected:
DOB:	Visit #:	Received:
Gender:	Location:	Reported:
Ordering MD:	Facility:	
Copy To:		

Specimen(s) Received

1. Adrenal: Left Resection
2. Lymph-Node: Para-aortic Supra Hilar node?
3. Gallbladder
4. Lymph node: Supra pancreatic lymph node
5. Retroperitoneum: vonhippel-landay syndrome
6. Vessel: Portal vein tissue
7. Reperitoneum
8. Pancreas: Whipple

Diagnosis

1. Pheochromocytoma: Adrenal (left) adrenalectomy specimen. See microscopic description.
2. Extra-adrenal paraganglioma: Ganglia, 1 of 3 (para-aortic suprahilar) biopsies.
3. No pathological diagnosis: Gallbladder
No pathological diagnosis: Lymph node, 1
- cholecystectomy specimen.
4. No pathological diagnosis: Lymph node, 1 (supra-pancreatic) biopsy.
- 5,6,7. Infiltrating neuroendocrine carcinoma: Soft tissue (#5 site not specified, portal vein and retroperitoneum) biopsies.
See comment.
8. Well-differentiated pancreatic neuroendocrine carcinoma, 5 cm in largest diameter, head of pancreas; multiple benign cysts, all resection margins negative, extending to within microscopic distance of the inked anterior margin:
Pancreas
No pathological diagnosis: Lymph nodes, 7
No pathological diagnosis: Stomach
No pathological diagnosis: Duodenum
- Whipple's resection specimen. See synoptic report.

Comment

Specimens 5,6 & 7. The biopsies consist of soft tissue with infiltrating cells that exhibit significant freezing artifact that precludes an accurate interpretation of morphology, however immunohistochemistry confirms positive for synaptophysin, cytokeratin 19 and focal reactivity for chromogranin; they are negative for tyrosine hydroxylase. The immunoprofile supports a diagnosis of neuroendocrine carcinoma and is similar to that of the pancreatic tumor.

[page 2 of 5]
Surgical Pathology Consultation Report

Synoptic Data

Specimen Type: Pancreaticoduodenectomy (Whipple resection), partial
Tumor Site: Pancreatic head
Tumor Focality: Unifocal
Tumor Configuration: Infiltrative
Tumor Size: Greatest dimension: 5.0 cm
Additional dimensions: 3.2 cm
Other Organs Submitted: Gallbladder
Other: left adrenal gland
Functional Type: Pancreatic endocrine tumor, secretory status unknown
Extent of Invasion: Tumor limited to pancreas
No regional lymph node metastasis
Number of regional lymph nodes examined: 9
Number of regional lymph nodes involved: 0
Distant metastasis
Margins: Margin(s) involved by invasive carcinoma
Margin(s) involved by invasive carcinoma - Other: SPECIMENS 5 (NOT SPECIFIED),
6 (PORTAL VEIN) AND 7 (RETROPERITONEUM)
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
Perineural Invasion: Absent
Mitotic Activity: Absent
Immunohistochemistry: Synaptophysin: positive
Chromogranin: positive
Insulin: focally positive
Glucagon: negative
Somatostatin: negative
Pancreatic polypeptide: negative
Gastrin: negative
Serotonin: negative
CK 19: positive
Ki-67: <1%
Other (specify): VIP: negative
Additional Pathologic Findings: Other: PanIN1 and serous adenomas

Electronically verified by:

Clinical History

Tumour of the pancreas

Gross Description

1. The specimen labeled with the patient's name and as "adrenal left resection" consists of an adrenal gland with adherent fatty tissue; it weighs 100.2 g and measures 9.5 x 6.3 x 4.7 cm. It is painted with silver nitrate. After the fat is removed, the adrenal with its mass weighs 78 g and measures 6 x 6.5 x 5.0 cm. On section the cut surface is solid brown tan with areas of hemorrhagic discoloration.

1A-O representative sections submitted.

2. The specimen container labeled with the patient's name and as "paraortic suprahilar node" contains a piece of fibrofatty tissue that measures 3.5 x 2.5 x 1.5 cm and contains 3 nodules that measure 0.4 x 0.4 x 0.3cm to 1.5 x 1 x 0.6cm. The nodes are submitted in toto.

2A 1 nodule bisected

2B 2 nodules

[page 3 of 5]
Surgical Pathology Consultation Report

3. The specimen is labeled with the patient's name and as "gallbladder".

Resection specimen: Gallbladder

MEASUREMENTS:

Length 9 cm.

Maximum diameter 3.5 cm.

DESCRIPTION OF GALLBLADDER:

Serosa: smooth

Adventitial surface: size: 7 x 2.5 cm appearance: Normal

Wall: Intact; 0.1 cm average thickness

Mucosa: velvety

Contents: Green bile; no stones.

Cystic duct:

- stenosis: No

- stone in lumen: No

- intraluminal tumor: No

Cystic duct lymph node: 1, measuring 0.4 x 0.2 x 0.2 cm

FOCAL LESIONS: No

TISSUE BANKING: No

Representative sections are submitted as follows:

3A cystic duct, body and fundus

3B node

4. The specimen labeled with the patient's name and as "supra pancreatic lymph node" consists of a lymph node that measures 0.9 x 0.9 x 0.6 cm.

4A bisected and submitted in toto.

5. The specimen labeled with the patient's name and as "von Hippel Landau lymph node" consists of a fragment of tissue that measures 0.3 x 0.3 x 0.2 cm. The specimen is frozen for intraoperative consultation.

5A frozen section block resubmitted

6. The specimen labeled with the patient's name and as "portal vein tissue" consists of a fragment of tissue that measures 0.5 x 0.3 x 0.2 cm. The specimen is frozen for intraoperative consultation.

6A frozen section block resubmitted

7. The specimen labeled with the patient's name and as "retroperitoneum" consists of a fragment of tissue that measures 0.4 x 0.3 x 0.2 cm. The specimen is frozen for intraoperative consultation.

7A frozen section block resubmitted

8. The specimen labeled with the patient's name and as "Whipple" consists of a Whipple resection including pancreas head, distal stomach, duodenum

Fixation: fixed

Dimensions:

- stomach: length along greater curvature: 4.5cm, circumference at proximal margin 17 cm; circumference at pylorus: 4.5cm

- duodenum: length: 28cm circumference proximal: 7.5 cm circumference distal: 7.8cm

- common bile duct: length: 4.8cm, circumference at proximal end: 1.3 cm; circumference at mid-point: 1cm circumference at distal end: 1 cm

- pancreas: 4.5 cm SI x 3 cm AP x 7.5 cm ML

- ampulla: length: 1cm, circumference: 0.6cm

TUMOR:

Location: head of pancreas; 1.2 cm from distal pancreatic margin

Configuration: solid

Dimensions: 3.2 cm SI x 5 cm ML x 3 cm AP

Characteristics: yellow, white, fibrous; partly calcified

Estimated extent of invasion: approaching anterior surface

OTHER LESIONS/FINDINGS IN REMAINDER OF PANCREAS: multiple cysts containing clear fluid in the remaining pancreas ranging in size from 0.2 to 1.3 cm

GROSS APPEARANCE OF STOMACH: Normal

[page 4 of 5]
Surgical Pathology Consultation Report

GROSS APPEARANCE OF DUODENUM: normal

GROSS APPEARANCE OF AMPULLA: normal

- tumor: no
- periampullary tumor: no

GROSS APPEARANCE OF COMMON BILE DUCT:

- appearance of mucosa normal
- stenosis: no
- intraluminal tumor: no
- tumor invading wall: no

MARGINS: Painted:

- distal pancreatic margin: India ink
- posterior pancreatic margin: silver nitrate
- retroperitoneal pancreatic margin: green ink

Distance of tumor to posterior/retroperitoneal margin of pancreas: 0.1 cm

Distance of tumor to distal margin of pancreas: 1.2 cm

Distance of tumor to CBD margin: 2.5cm

REGIONAL LYMPH NODES:

- Peri-CBD lymph nodes: number: 1 size range: 0.4 cm
- Peri-pancreatic lymph nodes: number: 3; size range: 0.8 to 1.6cm
- Peri-gastric lymph nodes: number: 2 size range: 0.3 to 0.8 cm

OTHER FINDINGS: The specimen overall has a pale gray appearance.

Tissue Banking: no

Representative sections are submitted as follows:

- 8A distal pancreatic margin en face
- 8B retroperitoneal margin perpendicularly cut
- 8C posterior pancreatic margin
- 8D common bile duct margin en face
- 8E-G proximal en face gastric margin
- 8H-I distal en face duodenal margin
- 8J mid CBD
- 8K ampulla
- 8L-M tumor approaching anterior surface pancreas
- 8N-O tumor
- 8P-Q cystic areas of pancreas
- 8R CBD node
- 8S 2 lymph nodes
- 8T one peripancreatic node bisected
- 8U 2 peripancreatic nodes bisected

Quick Section Diagnosis

5A – Portal vein tissue – Fibrotic tissue with aggregates of atypical cells, suspicious for a malignant neoplasm. Await permanent sections. Slide received:

6A – Retroperitoneum – Fibrotic tissue with aggregates of atypical cells, suspicious for a malignant neoplasm. Await permanent sections. Slide received:

7A – Retroperitoneum – Fibrotic tissue with aggregates of atypical cells, suspicious for a malignant neoplasm. Await permanent sections. Slide received:

Microscopic Description

1. Site: left adrenal gland

Tumour size: 6.5 x 6.2 x 4.7 cm

Histological pattern: Classical nested.

Cell type: polygonal (chief cells) and spindle (sustentacular cells).

Mitoses: 1 per 50 HPF

Necrosis: absent.

Other: extensive stromal hyalinization.

Lymphovascular invasion: absent.

Perineural invasion: absent.

[page 5 of 5]
Surgical Pathology Consultation Report

Extent/depth of invasion:
Underlying medullary hyperplasia: negative
Lymph nodes:
Number examined: none
Number involved: none
Metastasis: not known.
Immunohistochemistry:
i) synaptophysin:
ii) chromogranin
iii) S-100
iv) tyrosine hydroxylase

*Synchronous: neuroendocrine carcinoma - pancreas
extra-adrenal paraganglioma - ganglia
nos*

Criteria	W 7/3/13	Yes	No
Prior Malignancy History	SPINE		✓
Dual/Synchronous Primary Noted	Para. Pancreas		

Source: NCI Genomic Data Commons file 5e8fdbc4-4abd-41b3-99e9-e5deae872b07 (TCGA-SP-A6QH.C1B7A19E-D055-425B-AB0F-E2CFB3339385.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).